Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16E, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16E-01A (Primary Tumor).

ICD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/1/10

Site Code: Endometrium C54.1 *hw*

Surgical Pathology

TISSUE DESCRIPTION:

: A1 A2 A3 A4 A5 B1 B2 B3 C1 C2

Uterus (41.3 grams), right ovary (2.7 x 1.7 x 0.8 cm) with 4.3 cm

segment of right fallopian tube, and left ovary (3.6 x 2.8 x 1.7 cm)

with 3.2 cm segment of left fallopian tube.

DIAGNOSIS:

Uterus, hysterectomy: FIGO grade I (of III) endometrial adenocarcinoma, endometrioid type is identified forming a polypoid

mass (2.1 x 1.7 x 1.2 cm) at the left cornu. The tumor invades 0.2

cm into the myometrium (total myometrial thickness, 0.8 cm). There

is no lymphovascular space invasion. The endocervix is uninvolved.

The cervix is unremarkable.

Ovary, left, oophorectomy: Fibroma (2.9 x 2.3 x 1.7 cm).

Ovary, right, oophorectomy: Atrophic.

Fallopian tubes, left and right, salpingectomy: Unremarkable.

TIPTA Discrepancy		

hw *DISQUALIFIED*

Source: NCI Genomic Data Commons file b8c81061-cf36-4799-b9c3-4b0f571df9d9 (TCGA-D1-A16E.DF926973-D344-48AE-A6F6-5901A4A8C846.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).